Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0U2, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0U2-01A (Primary Tumor).

Breast, left, radical mastectomy: Infiltrating ductal carcinoma, Nottingham grade III (of III) forming a 3.2 x 2.2 x 1.6 cm mass (AJCC pT2) adjacent to the biopsy cavity in the central breast. Two separate microscopic foci (>2.0 mm) of invasive carcinoma are present in subareolar tissue in association with high grade (nuclear grade 3) ductal carcinoma in situ. Angiolymphatic invasion is identified. The surgical resection margins are negative for tumor.

Lymph nodes, left axillary, lymphadenectomy: Metastatic adenocarcinoma, consistent with breast origin, is identified involving multiple (4 of 16) axillary lymph nodes. The largest metastatically involved node measures 3.0 cm in maximum dimension and shows extracapsular tumor extension (AJCC pN2).

Fallopian tubes and ovaries, right and left, salpingo-oophorectomy: Fallopian tubes and ovaries showing no diagnostic abnormalities.

Estrogen and progesterone receptor analysis and her2-Neu have been ordered on paraffin embedded tissue.

WHO Discrepancy		X

Source: NCI Genomic Data Commons file 7b800c99-636d-4205-aacf-72bd3769b74a (TCGA-AR-A0U2.51F69645-9564-4257-A86E-3A574C27034F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).